Somatic mutation profile of tumor specimen MP2PRT-PASYWZ-TMP1-A (aliquot MP2PRT-PASYWZ-TMP1-A-1-0-D-A83O-36) from MP2PRT case MP2PRT-PASYWZ, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.6 years (1,683 days).
Specimen MP2PRT-PASYWZ-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f9cf193c-eeb0-4ce2-a957-89d23dcab908.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PASYWZ-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PASYWZ-NB1-A-1-0-D-A83O-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1b67297f-d69b-4f15-a34a-ebb0351f2316

The open-access MAF lists 33 somatic variants for this specimen: 21 protein-altering or splice-affecting, 10 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 20, Silent 10, 3'Flank 1, 5'UTR 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANKRD30BL | c.38C>T p.T13M | Missense Mutation (SNP) | VAF 127/333 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs751958828; called by muse, mutect2, varscan2
- CNTNAP3 | c.3409G>A p.A1137T | Missense Mutation (SNP) | VAF 177/233 reads (76%) | SIFT tolerated (0.18); PolyPhen benign (0.153); catalogued as rs767541305, COSV52666529; called by muse, varscan2
- CSMD3 | c.9808G>C p.V3270L (on ENST00000297405 / NM_001363185.1; = p.V3101L on NM_052900.3) | Missense Mutation (SNP) | VAF 339/584 reads (58%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.823); catalogued as rs151006759; called by muse, mutect2, varscan2
- FAM47B | c.203C>T p.T68M | Missense Mutation (SNP) | VAF 346/740 reads (47%) | SIFT tolerated (0.23); PolyPhen benign (0.071); catalogued as rs1447954737, COSV61454332, COSV61455302; called by muse, mutect2, varscan2
- NBPF12 | c.2155G>C p.E719Q | Missense Mutation (SNP) | VAF 44/237 reads (19%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.55); catalogued as rs1383168889; called by muse, mutect2, varscan2
- SFRP1 | c.442G>T p.G148C | Missense Mutation (SNP) | VAF 51/681 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.965); catalogued as COSV99616957; called by muse, mutect2
- TAS2R13 | c.148A>T p.I50F | Missense Mutation (SNP) | VAF 313/713 reads (44%) | SIFT tolerated (0.78); PolyPhen benign (0.005); catalogued as rs1445273246; called by muse, mutect2, varscan2
- TNF | c.323G>A p.R108Q | Missense Mutation (SNP) | VAF 384/854 reads (45%) | SIFT tolerated (0.29); PolyPhen benign (0.32); catalogued as rs747115001, COSV69305375; called by muse, mutect2, varscan2
- UGT1A10 | c.28G>A p.V10I | Missense Mutation (SNP) | VAF 168/380 reads (44%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs749394452; called by muse, mutect2, varscan2
- C1orf105 | c.382C>T p.P128S | Missense Mutation (SNP) | VAF 176/387 reads (45%) | SIFT tolerated (0.72); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- CDH1 | c.238G>T p.D80Y | Missense Mutation (SNP) | VAF 199/488 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- CFAP91 | c.157C>A p.H53N | Missense Mutation (SNP) | VAF 101/397 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- CSMD3 | c.847T>A p.F283I | Missense Mutation (SNP) | VAF 49/698 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- ETV6 | c.329-1_329dup p.X110_splice | Splice Site (INS) | VAF 126/366 reads (34%) | called by mutect2, pindel, varscan2
- KDM3A | c.3882A>T p.L1294F | Missense Mutation (SNP) | VAF 138/283 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KIF4B | c.3078A>C p.K1026N | Missense Mutation (SNP) | VAF 18/510 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.287); called by muse, mutect2
- LRRC71 | c.628C>A p.Q210K | Missense Mutation (SNP) | VAF 123/491 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.313); called by muse, mutect2, varscan2
- MEFV | c.2014A>G p.T672A | Missense Mutation (SNP) | VAF 24/623 reads (4%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- SHROOM3 | c.2246C>T p.S749L | Missense Mutation (SNP) | VAF 274/627 reads (44%) | SIFT tolerated (0.37); PolyPhen benign (0); called by muse, mutect2, varscan2
- TCEAL5 | c.238G>T p.G80C | Missense Mutation (SNP) | VAF 181/680 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- WDR59 | c.694C>T p.P232S | Missense Mutation (SNP) | VAF 118/402 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ANO3 | c.1455C>A p.V485= | Silent (SNP) | VAF 108/245 reads (44%) | called by muse, mutect2, varscan2
- FAM241B | c.42C>T p.D14= | Silent (SNP) | VAF 165/658 reads (25%) | catalogued as rs769897866, COSV64767984; called by muse, mutect2
- FTSJ3 | c.225G>A p.V75= | Silent (SNP) | VAF 153/338 reads (45%) | called by muse, mutect2, varscan2
- FURIN | c.468C>T p.I156= | Silent (SNP) | VAF 62/403 reads (15%) | catalogued as rs373576771; called by muse, mutect2, varscan2
- GPAM | c.1599A>G p.V533= | Silent (SNP) | VAF 21/562 reads (4%) | catalogued as rs1259177757, COSV62082665; called by muse, mutect2
- KCNT1 | c.1701C>T p.H567= (on ENST00000488444; = p.H586= on NM_020822.3) | Silent (SNP) | VAF 160/355 reads (45%) | catalogued as rs142760483; called by muse, mutect2, varscan2
- LPXN | c.1044C>T p.F348= | Silent (SNP) | VAF 249/623 reads (40%) | called by muse, mutect2, varscan2
- LVRN | c.678C>T p.T226= | Silent (SNP) | VAF 142/326 reads (44%) | catalogued as rs778369338, COSV100773258; called by muse, mutect2
- SLCO2B1 | c.1260G>A p.S420= | Silent (SNP) | VAF 255/420 reads (61%) | catalogued as rs753724002; called by muse, mutect2, varscan2
- TTPAL | c.195G>T p.V65= | Silent (SNP) | VAF 52/680 reads (8%) | called by muse, mutect2
- IGKV3D-11 | chr2:90173414 ins AA | 3'Flank (INS) | VAF 114/180 reads (63%) | called by mutect2, pindel, varscan2
- TTYH3 | c.-103C>G | 5'UTR (SNP) | VAF 207/478 reads (43%) | called by muse, mutect2, varscan2
